Somatic mutation profile of tumor specimen TCGA-ZB-A96C-01A (aliquot TCGA-ZB-A96C-01A-11D-A428-09) from TCGA case TCGA-ZB-A96C, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 77.3 years (28,222 days).
Specimen TCGA-ZB-A96C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 336c9ff5-08ca-4156-8a01-07ed2f2e400c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96C-10A (Blood Derived Normal), aliquot TCGA-ZB-A96C-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5051e4e4-62dc-4881-9b6b-54af3e998a81

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 142/438 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- LFNG | c.766G>A p.G256S (on ENST00000222725 / NM_001040167.2; = p.G127S on NM_002304.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1437427476; called by muse, mutect2, varscan2
- MED13 | c.5866T>G p.S1956A | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1367047163; called by muse, mutect2
- SACS | c.4606G>T p.V1536L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs764832688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A6 | c.1367C>A p.T456K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs777129743; called by muse, varscan2
- BBS10 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FILIP1 | c.2804T>C p.F935S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GPR173 | c.403A>G p.M135V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GRM8 | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HES1 | c.795C>G p.S265R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGFLR1 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.78); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IQCA1 | c.2126C>A p.S709Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- L3MBTL3 | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- OR6M1 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHEX | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PTPRN | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RPGR | c.2477A>G p.E826G (on ENST00000339363 / NM_001367249.1; = p.E621G on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPIRE2 | c.2101C>T p.Q701* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- TMEM185A | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP9A | c.2955G>C p.L985= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, varscan2
- CFAP65 | c.4948A>C p.R1650= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1403968225, COSV58560393; called by muse, mutect2, varscan2
- MAMDC4 | c.1515C>T p.D505= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs778576073; called by muse, varscan2
- MXRA5 | c.6129G>C p.A2043= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV54230785; called by muse, mutect2, varscan2
- PPFIA2 | c.2745G>A p.A915= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs376356533; called by muse, mutect2, varscan2
- ZSCAN16 | c.762C>T p.H254= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs113926481; called by muse, mutect2, varscan2
